Somatic mutation profile of tumor specimen TCGA-86-7953-01A (aliquot TCGA-86-7953-01A-11D-2184-08) from TCGA case TCGA-86-7953, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 69.3 years (25,315 days).
Specimen TCGA-86-7953-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e6b8d4b-6a0f-4c9d-af8c-5a6f592aa5fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-7953-10A (Blood Derived Normal), aliquot TCGA-86-7953-10A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6171ad0-d84d-46c2-adaa-500b7b45bbbb

The open-access MAF lists 54 somatic variants for this specimen: 43 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 10, Nonsense Mutation 2, Translation Start Site 1, Splice Region 1, 5'UTR 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 12/55 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP000311.1 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.05); catalogued as COSV51708458, COSV51709234; called by muse, mutect2, varscan2
- ARID5B | c.2435A>G p.K812R | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV54421516; called by muse, varscan2
- BRD8 | c.645C>T p.V215= (on ENST00000254900 / NM_139199.2; = p.V288= on NM_006696.4) | Splice Region (SNP) | VAF 34/119 reads (29%) | catalogued as COSV50150304; called by muse, mutect2, varscan2
- C8A | c.86G>A p.R29K | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV63484408; called by muse, mutect2, varscan2
- CACNA1A | c.4300G>A p.A1434T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.439); catalogued as COSV64199591; called by muse, mutect2, varscan2
- CCT6A | c.874A>G p.I292V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV51905828; called by muse, mutect2, varscan2
- CH25H | c.531G>T p.W177C | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV64092347; called by muse, mutect2, varscan2
- EFHC2 | c.1657C>A p.L553M | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.437); catalogued as COSV59093455, COSV59093965; called by muse, mutect2, varscan2
- FAM13A | c.1559G>T p.G520V | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV52003480; called by muse, mutect2, varscan2
- FAM13C | c.827G>T p.S276I | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1200548230, COSV53248597; called by muse, mutect2, varscan2
- FBXL12 | c.275C>G p.A92G | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV56114242; called by muse, mutect2, varscan2
- GHR | c.1768A>C p.M590L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV50114295; called by muse, mutect2, varscan2
- GRIA3 | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.994); catalogued as COSV52062353; called by muse, mutect2, varscan2
- HEPH | c.2078G>T p.G693V (on ENST00000343002; = p.G426V on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57964781; called by muse, mutect2, varscan2
- KCNK18 | c.533C>A p.S178Y | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV57971929; called by muse, mutect2, varscan2
- KPNB1 | c.1428T>A p.S476R | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV51597303; called by muse, mutect2, varscan2
- LRIG3 | c.3151G>A p.D1051N | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); catalogued as rs754342100, COSV57863621; called by muse, mutect2
- LTV1 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs757304900, COSV52786869; called by muse, mutect2, varscan2
- NKTR | c.2551C>T p.R851W | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs371760266, COSV51769510; called by muse, mutect2, varscan2
- NMS | c.296C>G p.A99G | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.866); catalogued as COSV65258720; called by muse, mutect2, varscan2
- NR3C2 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.786); catalogued as COSV60991711; called by muse, mutect2, varscan2
- OSBPL6 | c.1949C>A p.P650Q | Missense Mutation (SNP) | VAF 16/462 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51919367; called by muse, mutect2
- PCDH10 | c.2488G>A p.A830T | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.207); catalogued as COSV52086621; called by muse, mutect2, varscan2
- PCDHB11 | c.68T>C p.M23T | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.028); catalogued as COSV53379447; called by muse, mutect2
- PPEF1 | c.911A>T p.K304M | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV62995848; called by muse, mutect2, varscan2
- PPP4C | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 14/58 reads (24%) | catalogued as COSV54224308; called by muse, mutect2, varscan2
- SEMA6D | c.2009C>A p.A670D (on ENST00000316364 / NM_153618.2; = p.A608D on NM_020858.2) | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV60377891; called by muse, mutect2, varscan2
- SERPINB4 | c.1142T>A p.I381N | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61985072; called by muse, mutect2, varscan2
- SLC5A2 | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57891992; called by muse, mutect2, varscan2
- SLC6A11 | c.1237G>C p.V413L | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV54394156; called by muse, mutect2
- SMARCE1 | c.591G>T p.Q197H | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.074); catalogued as COSV52861082; called by muse, mutect2, varscan2
- SNF8 | c.703T>C p.W235R | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51726723; called by muse, mutect2, varscan2
- SRPK2 | c.905T>C p.I302T | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV61961334; called by muse, mutect2, varscan2
- TAOK1 | c.584T>G p.L195* | Nonsense Mutation (SNP) | VAF 52/256 reads (20%) | catalogued as COSV55592397; called by muse, mutect2, varscan2
- TTBK1 | c.3073G>T p.A1025S | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.007); catalogued as COSV52491962; called by muse, mutect2, varscan2
- USP38 | c.793G>T p.A265S | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.314); catalogued as COSV100189092; called by muse, mutect2, varscan2
- USP38 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.213); catalogued as COSV100189094; called by muse, mutect2, varscan2
- ZIC4 | c.308T>A p.L103Q | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as COSV67172028; called by muse, mutect2
- ZNF789 | c.912G>T p.Q304H | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV58874431; called by muse, mutect2, varscan2
- SLC1A7 | c.-6_21del | Translation Start Site (DEL) | VAF 5/42 reads (12%) | called by mutect2, pindel
- TP53 | c.342_358del p.H115Vfs*28 | Frame Shift Del (DEL) | VAF 21/95 reads (22%) | called by mutect2, pindel, varscan2
- UTP20 | c.5540dup p.L1847Ffs*69 | Frame Shift Ins (INS) | VAF 7/65 reads (11%) | called by mutect2, pindel, varscan2
- CES5A | c.903G>A p.L301= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV51866749; called by muse, mutect2, varscan2
- FRMD4B | c.2205A>G p.Q735= | Silent (SNP) | VAF 31/129 reads (24%) | catalogued as rs377617300; called by muse, mutect2, varscan2
- GRIN2A | c.1485A>T p.G495= | Silent (SNP) | VAF 50/193 reads (26%) | catalogued as COSV58035545; called by muse, mutect2, varscan2
- KMT2C | c.3864G>T p.R1288= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as COSV51445198; called by muse, mutect2, varscan2
- NEDD1 | c.69A>C p.T23= | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as COSV57143750; called by muse, mutect2, varscan2
- NEUROD6 | c.555C>T p.A185= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as COSV51771618; called by muse, mutect2
- PRKD3 | c.1939C>A p.R647= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV52211929, COSV52213915; called by muse, mutect2, varscan2
- VCAN | c.213G>T p.V71= | Silent (SNP) | VAF 29/116 reads (25%) | catalogued as COSV54106315; called by muse, mutect2, varscan2
- WDR59 | c.663C>T p.Y221= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV50936311, COSV50941705; called by muse, mutect2
- XRCC5 | c.708C>G p.V236= | Silent (SNP) | VAF 11/163 reads (7%) | catalogued as COSV67536395; called by muse, mutect2
- RBAK | c.-66G>C | 5'UTR (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100806555; called by muse, mutect2, varscan2
